Gene-level copy-number profile of tumor specimen TCGA-24-1427-01A from TCGA case TCGA-24-1427, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.7 years (21,423 days).
Specimen TCGA-24-1427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.964da6cb-96ff-4da6-a8ea-20438f061d78.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1427-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9545551f-53d9-4581-9511-478a9a0d1442

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,227; copy number 2: 18,678; copy number 3: 21,161; copy number 4: 9,522; copy number 5: 4,416; copy number 6: 1,599; copy number 7: 417; copy number 8: 155; copy number 9: 177; copy number 10: 117; copy number 11: 325; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1427-01A-01D-0472-01): tumor purity 0.57, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:61,638,233–63,181,071, 13 genes: AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2.
- chr22:29,554,808–29,698,598, 3 genes (within-gene range 0–2): NIPSNAP1, NF2, RPEP4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,196 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,923,670–164,980,137, 13 genes, copy number 7: U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:165,210,627–165,219,104, 2 genes, copy number 7: LMX1A-AS2, LMX1A-AS1.
- chr1:177,170,958–178,499,634, 14 genes, copy number 7: BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP.
- chr3:77,092,057–82,463,675, 35 genes, copy number 7 (within-gene range 4–7): RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr4:71,062,667–76,783,253, 99 genes, copy number 10–12 (within-gene range 4–12) (broad region; genes not listed).
- chr8:86,707,547–137,698,467, 695 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr10:274,190–689,668, 1 gene, copy number 9 (within-gene range 2–9): DIP2C.
- chr10:430,239–11,336,675, 184 genes, copy number 8–9 (within-gene range 1–9) (broad region; genes not listed).
- chr10:15,513,954–16,821,207, 14 genes, copy number 7: ITGA8, MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2.
- chr12:38,532,895–43,163,110, 64 genes, copy number 7 (broad region; genes not listed).
- chr12:46,764,761–48,529,897, 75 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
